Somatic mutation profile of tumor specimen TCGA-CM-4743-01A (aliquot TCGA-CM-4743-01A-01D-1719-10) from TCGA case TCGA-CM-4743, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.2 years (25,291 days).
Specimen TCGA-CM-4743-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d46d6d8-bb77-4f91-b69d-d60913ac6157.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-4743-10A (Blood Derived Normal), aliquot TCGA-CM-4743-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e81cce1-1ed4-408b-a1f2-7fdf79bc8403

The open-access MAF lists 1,417 somatic variants for this specimen: 1,085 protein-altering or splice-affecting, 309 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 742, Silent 309, Frame Shift Del 221, Frame Shift Ins 55, Splice Site 23, Nonsense Mutation 21, In Frame Del 11, Intron 8, RNA 7, Splice Region 6, Nonstop Mutation 3, 3'UTR 3.

Variants (750 of 1,417; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL10 | c.499del p.S167Lfs*6 | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | catalogued as rs387906350, COSV65354275; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 42/219 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- COL7A1 | c.6187C>T p.R2063W | Missense Mutation (SNP) | VAF 79/394 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs121912849, CM970380, CM970381, COSV60392347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 51/114 reads (45%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- IVD | c.158G>A p.R53H (on ENST00000651168; = p.R50H on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs2229311, CM043002, CM074290, CM983433; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- MCCC1 | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 76/293 reads (26%) | catalogued as rs1484347924, CM062844, COSV55606885; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RIN2 | c.1878del p.I627Sfs*4 (on ENST00000255006 / NM_001242581.1; = p.I578Sfs*4 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RYR1 | c.11320dup p.A3774Gfs*37 | Frame Shift Ins (INS) | VAF 16/81 reads (20%) | catalogued as rs768698639; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TBCK | c.1370dup p.N457Kfs*10 (on ENST00000273980 / NM_001163436.4; = p.N394Kfs*10 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/144 reads (22%) | catalogued as rs746860249; ClinVar: pathogenic; called by mutect2, varscan2
- TGFBR2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893810, CM050761, CM140638, COSV55443375, COSV55461069, COSV99848566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGM1 | c.1928-1G>A p.X643_splice | Splice Site (SNP) | VAF 20/86 reads (23%) | catalogued as rs112419023, COSV52862192; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.15del p.K5Nfs*15 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs878854133; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA13 | c.7225C>A p.L2409I | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV71284486; called by muse, mutect2, varscan2
- ABCA2 | c.5005G>A p.V1669I (on ENST00000614293; = p.V1639I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs559737748, COSV55798567; called by muse, mutect2
- ABCA2 | c.4181C>T p.S1394L (on ENST00000614293; = p.S1364L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs771596724, COSV55798584; called by muse, mutect2, varscan2
- ABCA2 | c.2839G>A p.V947M (on ENST00000614293; = p.V917M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99686622; called by muse, mutect2
- ABCA4 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs765680067, COSV64671733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB9 | c.2167A>G p.T723A (on ENST00000280560 / NM_019625.4; = p.T680A on NM_019624.3) | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV54890628; called by muse, varscan2
- ABCC1 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs756498834, COSV60681960; called by muse, mutect2, varscan2
- ABCC4 | c.3566G>T p.R1189M | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65310454; called by muse, mutect2, varscan2
- ABCD2 | c.1469_1471del p.G490del | In Frame Del (DEL) | VAF 11/73 reads (15%) | catalogued as rs758097606; called by mutect2, pindel, varscan2
- ABCF3 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53047349; called by muse, mutect2, varscan2
- ABHD1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs150190890; called by muse, mutect2, varscan2
- ABR | c.2526del p.I843Ffs*41 (on ENST00000302538 / NM_021962.5; = p.I806Ffs*41 on NM_001092.5) | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs750897785; called by mutect2, varscan2
- ABR | c.961G>A p.V321I (on ENST00000302538 / NM_021962.5; = p.V284I on NM_001092.5) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as rs778794313, COSV52142593; called by muse, mutect2, varscan2
- AC004997.1 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0); catalogued as rs756306909, COSV57575126; called by muse, mutect2, varscan2
- AC011455.2 | c.1557G>T p.T519= | Splice Region (SNP) | VAF 22/86 reads (26%) | catalogued as COSV55498694; called by muse, mutect2, varscan2
- ACACA | c.5227G>A p.A1743T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs199723320; called by muse, mutect2, varscan2
- ACCSL | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs764834531, COSV66580511, COSV66582266; called by muse, mutect2, varscan2
- ACTC1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.411); catalogued as rs944740404, COSV51757427; called by muse, mutect2, varscan2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 42/223 reads (19%) | catalogued as COSV57774850; called by muse, mutect2, varscan2
- ADAM7 | c.390-1G>T p.X130_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as COSV51536284; called by muse, mutect2, varscan2
- ADAMTS15 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs765064754, COSV54503421; called by muse, mutect2, varscan2
- ADAMTS4 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV63487429; called by muse, mutect2, varscan2
- ADAMTSL1 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99443262; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2491C>A p.P831T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV54997488; called by muse, mutect2, varscan2
- ADCK1 | c.1217T>C p.I406T | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs765285872, COSV53078650; called by muse, mutect2, varscan2
- ADGRV1 | c.12865A>G p.I4289V | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67980129; called by muse, mutect2, varscan2
- ADM | c.530del p.P177Rfs*12 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs773405081; called by mutect2, pindel, varscan2
- ADORA2A | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV100418059; called by muse, mutect2, varscan2
- AFAP1 | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV61794023; called by muse, mutect2, varscan2
- AFDN | c.3764del p.K1255Sfs*38 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | catalogued as COSV60050381; called by mutect2, pindel, varscan2
- AHDC1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1453259977, COSV55937289; called by muse, mutect2, varscan2
- AHNAK | c.2843T>C p.M948T | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57206215; called by muse, mutect2, varscan2
- AHRR | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs749711222, COSV57088478; called by muse, mutect2, varscan2
- AIMP2 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs764843355, COSV52237017; called by muse, mutect2, varscan2
- AK1 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV56344840, COSV56345062; called by muse, mutect2, varscan2
- AKAP12 | c.3479del p.P1160Lfs*18 | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | catalogued as COSV53580835; called by mutect2, pindel, varscan2
- AKAP17A | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.841); catalogued as rs752093256, COSV100002297; called by muse, mutect2, varscan2
- ALB | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776185501, COSV99891595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH18A1 | c.644T>C p.I215T | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV64662220; called by muse, mutect2, varscan2
- ALDH5A1 | c.1172A>G p.K391R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1479093682, COSV62372941; called by muse, mutect2, varscan2
- ALG10 | c.486del p.F162Lfs*4 | Frame Shift Del (DEL) | VAF 99/552 reads (18%) | catalogued as COSV99847982; called by mutect2, varscan2
- ALKBH5 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.837); catalogued as COSV52753305; called by muse, mutect2, varscan2
- ANGEL1 | c.1730T>C p.V577A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV51872152; called by muse, mutect2, varscan2
- ANGPTL7 | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.462); catalogued as COSV63869139; called by muse, mutect2, varscan2
- ANKAR | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs542000323, COSV51461960; called by muse, mutect2, varscan2
- ANKMY2 | c.395T>C p.I132T | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs771078807, COSV61011233; called by muse, mutect2, varscan2
- ANKRD16 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV51946937; called by muse, mutect2, varscan2
- ANKRD49 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as rs1250295325, COSV57059873; called by muse, mutect2, varscan2
- AOC3 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs762768941, COSV53826071; called by muse, mutect2, varscan2
- AP1M1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99358435; called by muse, mutect2, varscan2
- AP1M2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV51565887; called by muse, mutect2, varscan2
- APBA2 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV101382287; called by muse, mutect2, varscan2
- APOB | c.6443dup p.Y2149Vfs*2 | Frame Shift Ins (INS) | VAF 42/225 reads (19%) | catalogued as COSV51933010; called by mutect2, pindel, varscan2
- APOBEC3A | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs374922066, COSV50779208; called by muse, mutect2, varscan2
- ARFGAP3 | c.180T>G p.S60R | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99605329; called by muse, mutect2, varscan2
- ARHGEF10 | c.2990del p.E997Gfs*16 (on ENST00000398564; = p.E972Gfs*16 on NM_014629.4) | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as COSV50643570; called by mutect2, pindel, varscan2
- ARHGEF18 | c.2074A>C p.S692R (on ENST00000359920 / NM_001130955.2; = p.S588R on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV60467823; called by muse, mutect2, varscan2
- ARHGEF2 | c.2300T>C p.F767S (on ENST00000361247 / NM_001162383.2; = p.F739S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV100560682; called by muse, mutect2, varscan2
- ARHGEF4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58118939, COSV58123932; called by muse, mutect2, varscan2
- ARL16 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs762321709, COSV61266932, COSV61268654; called by muse, mutect2, varscan2
- ARPP21 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.294); catalogued as COSV99492250; called by muse, mutect2, varscan2
- ARRDC3 | c.1078A>G p.N360D | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54364708, COSV54366116; called by muse, varscan2
- ART1 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51703270; called by muse, mutect2, varscan2
- ASAP2 | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs757456352, COSV99856318; called by muse, varscan2
- ASCC1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751027189, COSV54964273; called by muse, mutect2, varscan2
- ATAD3B | c.*1G>A | Splice Region (SNP) | VAF 77/504 reads (15%) | catalogued as rs750391230, COSV100426510; called by muse, mutect2, varscan2
- ATG2A | c.5036A>G p.Y1679C | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101034494; called by muse, mutect2, varscan2
- ATM | c.3993G>A p.Q1331= | Splice Region (SNP) | VAF 19/108 reads (18%) | catalogued as rs863224566, COSV53731830, COSV53754803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11B | c.423+2T>C p.X141_splice | Splice Site (SNP) | VAF 67/303 reads (22%) | catalogued as COSV100017838; called by muse, mutect2, varscan2
- ATP13A3 | c.2312T>C p.V771A | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV55462181; called by muse, varscan2
- ATP1B1 | c.567+2_567+3del p.X189_splice | Splice Site (DEL) | VAF 23/114 reads (20%) | catalogued as COSV63178981; called by mutect2, pindel, varscan2
- ATP2B2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760746487, COSV59488326; called by muse, mutect2, varscan2
- ATP4A | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV52866422; called by muse, mutect2, varscan2
- ATP6V0D2 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99571768; called by muse, mutect2, varscan2
- ATP8A1 | c.3020G>T p.S1007I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV52530634; called by muse, mutect2, varscan2
- ATR | c.3736C>T p.Q1246* | Nonsense Mutation (SNP) | VAF 27/167 reads (16%) | catalogued as COSV63384763; called by muse, mutect2, varscan2
- AZIN1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs764483089, COSV61480186, COSV61481208; called by muse, mutect2, varscan2
- B4GALNT4 | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV57322121; called by muse, mutect2, varscan2
- BANP | c.1369G>A p.A457T (on ENST00000286122; = p.A407T on NM_017869.4) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs776799978, COSV53734622; called by muse, mutect2, varscan2
- BBS12 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs776216693, COSV58561555; called by muse, mutect2, varscan2
- BBS12 | c.1378G>A p.V460M | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as rs776267938, COSV100044971; called by muse, mutect2, varscan2
- BCL11B | c.2501C>T p.A834V (on ENST00000357195 / NM_001282237.2; = p.A763V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61734162; called by muse, mutect2, varscan2
- BCL9L | c.3956C>T p.T1319M | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs150852065; called by muse, mutect2, varscan2
- BIRC6 | c.3605C>T p.T1202M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs979783504, COSV70196627; called by muse, mutect2, varscan2
- BMP4 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.284); catalogued as rs778657318, COSV99816800, COSV99816993; called by muse, mutect2, varscan2
- BNC2 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.253); catalogued as COSV66148244; called by muse, mutect2, varscan2
- BOP1 | c.110T>A p.L37H | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.439); catalogued as COSV56639161, COSV56639976; called by muse, mutect2, varscan2
- BPNT2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV52906851; called by muse, mutect2, varscan2
- BRD1 | c.2623C>T p.R875W (on ENST00000216267 / NM_001349940.1; = p.R1006W on NM_001304808.3) | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs941898991, COSV53455429; called by muse, mutect2, varscan2
- BRD2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66372606; called by muse, mutect2, varscan2
- BRINP2 | c.1827C>A p.S609R | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV64176185; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 77/174 reads (44%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTNL3 | c.391del p.V131Wfs*66 | Frame Shift Del (DEL) | VAF 31/173 reads (18%) | catalogued as COSV61565019; called by mutect2, pindel, varscan2
- C11orf87 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV59356272; called by muse, mutect2, varscan2
- C1QTNF6 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs140887252; called by muse, mutect2, varscan2
- C1orf56 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV54846093; called by muse, mutect2, varscan2
- C5 | c.2477A>G p.E826G | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV99798060; called by muse, mutect2, varscan2
- C5AR2 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.454); catalogued as rs762735311, COSV57255663; called by muse, mutect2, varscan2
- C8orf34 | c.409A>T p.N137Y | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV61373559; called by muse, mutect2, varscan2
- CABIN1 | c.5837C>T p.T1946I | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV54078933; called by muse, mutect2, varscan2
- CACNA1A | c.6613C>T p.R2205W | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477386827, COSV64192200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV53117462; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs745547658; called by mutect2, varscan2
- CAND1 | c.1355A>G p.Q452R | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV73389550; called by muse, mutect2, varscan2
- CAND2 | c.2894T>G p.L965R (on ENST00000456430 / NM_001162499.2; = p.L872R on NM_012298.3) | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99929291; called by muse, mutect2, varscan2
- CAP1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs374359120; called by muse, mutect2, varscan2
- CARMIL1 | c.3802G>A p.A1268T | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as COSV61515059; called by muse, mutect2, varscan2
- CAST | c.677T>C p.I226T (on ENST00000341926; = p.I309T on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1329562493; called by muse, mutect2
- CASZ1 | c.4004G>A p.R1335H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs531901811, COSV100681532; called by muse, mutect2, varscan2
- CATSPERD | c.1279-1G>T p.X427_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV58464538; called by muse, mutect2, varscan2
- CBX7 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs567409810, COSV53358500; called by muse, mutect2, varscan2
- CCBE1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs368065685; called by muse, mutect2, varscan2
- CCDC102A | c.914T>G p.L305R | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV50775893; called by muse, mutect2, varscan2
- CCDC141 | c.2743G>T p.D915Y | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148223435; called by muse, mutect2, varscan2
- CCDC157 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57837926; called by muse, mutect2, varscan2
- CCDC171 | c.3317G>A p.R1106H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as rs374545016; called by muse, mutect2, varscan2
- CCDC18 | c.1299C>A p.C433* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as COSV58141788; called by muse, varscan2
- CCDC42 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs143164438; called by muse, mutect2, varscan2
- CCNE1 | c.1006A>G p.M336V | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs748914866, COSV52903707; called by muse, mutect2, varscan2
- CCS | c.285dup p.P96Afs*16 | Frame Shift Ins (INS) | VAF 24/132 reads (18%) | catalogued as rs759691599; called by mutect2, varscan2
- CCSER1 | c.1639T>C p.C547R | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1349539530, COSV61414611; called by muse, mutect2, varscan2
- CD19 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as rs757806171, COSV61188015; called by muse, mutect2, varscan2
- CD248 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs373617917; called by muse, mutect2, varscan2
- CD276 | c.1549C>A p.L517M (on ENST00000318443 / NM_001024736.2; = p.L299M on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.435); catalogued as COSV100573385; called by muse, mutect2, varscan2
- CDC42BPG | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770214055, COSV61346045; called by muse, mutect2, varscan2
- CDH10 | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV52573495; called by muse, mutect2, varscan2
- CDH17 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1295150677, COSV99217518; called by muse, varscan2
- CDH8 | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.178); catalogued as COSV54853786; called by muse, mutect2, varscan2
- CDH9 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV99145656; called by muse, mutect2, varscan2
- CDHR3 | c.2456C>A p.A819D | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV58414867; called by muse, mutect2, varscan2
- CDK12 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749022057, COSV71000100; called by muse, mutect2, varscan2
- CDK13 | c.2639G>A p.R880H | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs761752355, COSV99475652; called by muse, mutect2, varscan2
- CEBPZ | c.2332A>G p.M778V | Missense Mutation (SNP) | VAF 81/429 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV99305254; called by muse, mutect2, varscan2
- CELSR1 | c.6902C>T p.P2301L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs538530181, COSV53085254; called by muse, mutect2, varscan2
- CEMIP | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); catalogued as COSV54989300; called by muse, mutect2, varscan2
- CEMIP2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as rs778331613, COSV100987406; called by muse, mutect2, varscan2
- CHD4 | c.5365C>T p.R1789C (on ENST00000357008 / NM_001363606.2; = p.R1800C on NM_001273.5) | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1480327213, COSV58895619; called by muse, mutect2, varscan2
- CHD7 | c.4607A>G p.K1536R | Missense Mutation (SNP) | VAF 76/376 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV71107701; called by muse, mutect2, varscan2
- CHERP | c.2054G>T p.R685M | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52222928; called by muse, mutect2, varscan2
- CHRD | c.1687T>G p.C563G | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52606120; called by muse, varscan2
- CHRD | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); catalogued as COSV52606129; called by muse, varscan2
- CHRD | c.2415dup p.F806Lfs*5 | Frame Shift Ins (INS) | VAF 40/195 reads (21%) | catalogued as rs1265267146; called by mutect2, pindel, varscan2
- CHRM1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100186211; called by muse, mutect2, varscan2
- CHRNA4 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs777222517, COSV100937429; called by muse, mutect2, varscan2
- CHUK | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as rs370134476; called by muse, mutect2, varscan2
- CLCF1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.616); catalogued as COSV56861413; called by muse, mutect2, varscan2
- CLUH | c.3578A>G p.Y1193C (on ENST00000435359; = p.Y1232C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV101425769; called by muse, mutect2, varscan2
- CNGA1 | c.1327dup p.T443Nfs*3 | Frame Shift Ins (INS) | VAF 79/398 reads (20%) | catalogued as rs772867912; called by mutect2, varscan2
- CNOT3 | c.1207A>C p.S403R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55362875, COSV99651975; called by muse, mutect2, varscan2
- CNTNAP2 | c.2951A>G p.Y984C | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV62154484; called by muse, mutect2, varscan2
- CNTRL | c.5405del p.K1802Sfs*9 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs1217756472; called by mutect2, pindel, varscan2
- COA5 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1305307057, COSV60830981; called by muse, mutect2, varscan2
- COG3 | c.2090G>A p.C697Y | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63071605, COSV63072636; called by muse, mutect2, varscan2
- COL12A1 | c.4780C>T p.R1594C | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1306651193, COSV59391478; called by muse, mutect2, varscan2
- COL4A6 | c.4306C>T p.P1436S | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.653); catalogued as COSV100564279; called by muse, mutect2
- COL6A6 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV62019719; called by muse, mutect2, varscan2
- COL6A6 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 47/180 reads (26%) | catalogued as rs777444690, COSV62018197; called by muse, mutect2, varscan2
- COL7A1 | c.6074G>C p.G2025A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766931219, CM071643, CM970377, COSV60392353; called by muse, mutect2, varscan2
- COL8A1 | c.1795dup p.H599Pfs*6 | Frame Shift Ins (INS) | VAF 20/83 reads (24%) | catalogued as rs753058238; called by mutect2, varscan2
- COMMD5 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1334257742, COSV57382884; called by muse, mutect2, varscan2
- COPB2 | c.1267T>A p.S423T | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV60812348; called by mutect2, varscan2
- COTL1 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs750865355, COSV52289625; called by muse, mutect2, varscan2
- CPE | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV68579607; called by muse, mutect2, varscan2
- CPEB4 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV54170192; called by muse, mutect2, varscan2
- CPS1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs148654695, COSV51804455; called by muse, mutect2, varscan2
- CPSF2 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1233574965, COSV54098870; called by muse, mutect2, varscan2
- CPXM2 | c.1690G>T p.D564Y | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV53858023; called by muse, mutect2, varscan2
- CRELD2 | c.153_155del p.K51del | In Frame Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs758383025; called by pindel, varscan2
- CRISPLD1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV51545252; called by muse, mutect2, varscan2
- CSF3 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1177855556, COSV56640127; called by muse, mutect2, varscan2
- CSF3R | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs776535279, COSV100117521, COSV58964271; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 38/166 reads (23%) | catalogued as rs747437399; called by mutect2, varscan2
- CSNK1A1L | c.881A>T p.Y294F | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV101131108; called by muse, mutect2
- CSRNP2 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV50396863; called by muse, mutect2, varscan2
- CTBP1 | c.1047C>G p.N349K | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV52072299; called by muse, mutect2, varscan2
- CTC1 | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as rs758206104, COSV59852456; called by muse, mutect2, varscan2
- CTCF | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as COSV50462726; called by muse, varscan2
- CTNNA2 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.169); catalogued as rs764740838, COSV58163403; called by muse, mutect2, varscan2
- CTR9 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs775426922, COSV63728110; called by muse, varscan2
- CYB5R4 | c.66dup p.R23Afs*2 | Frame Shift Ins (INS) | VAF 29/134 reads (22%) | catalogued as rs750790143; called by mutect2, pindel, varscan2
- CYP2A7 | c.953T>C p.M318T | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs760304356, COSV99394161; called by muse, mutect2, varscan2
- DAGLA | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs563788842, COSV57194790; called by muse, mutect2, varscan2
- DAXX | c.2210C>G p.S737* | Nonsense Mutation (SNP) | VAF 40/168 reads (24%) | catalogued as COSV56467413; called by muse, mutect2, varscan2
- DCAF10 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745707991, COSV54287398; called by muse, mutect2, varscan2
- DCDC2B | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52207908; called by muse, mutect2, varscan2
- DCHS1 | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as rs762213705, COSV55031970; called by muse, mutect2, varscan2
- DCHS1 | c.2428G>T p.G810C | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55031982; called by muse, mutect2, varscan2
- DDX24 | c.1919T>C p.V640A | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV58211956; called by muse, mutect2, varscan2
- DDX60L | c.2182A>G p.I728V | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as rs61736171, COSV52710201; called by muse, mutect2, varscan2
- DENND2B | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58201957; called by muse, mutect2, varscan2
- DENND2C | c.1870T>C p.F624L (on ENST00000393274 / NM_001256404.2; = p.F567L on NM_198459.4) | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV67920347; called by muse, mutect2, varscan2
- DENND6B | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766966660, COSV63780470; called by muse, mutect2, varscan2
- DGKA | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV59384854; called by muse, mutect2, varscan2
- DGKD | c.3269C>A p.P1090Q (on ENST00000264057 / NM_152879.3; = p.P1046Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.034); catalogued as COSV51035354, COSV51063593; called by muse, mutect2, varscan2
- DHX30 | c.811G>A p.V271M (on ENST00000445061 / NM_138615.3; = p.V232M on NM_014966.3) | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV100820062; called by muse, mutect2, varscan2
- DIDO1 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs771332438, COSV56615864; called by muse, mutect2, varscan2
- DIP2A | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs573159135, COSV59473894; called by muse, mutect2, varscan2
- DLX1 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV100249959; called by muse, mutect2, varscan2
- DMBX1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs372261765; called by muse, mutect2, varscan2
- DNAAF3 | c.1012C>T p.Q338* (on ENST00000524407 / NM_001256715.2; = p.Q385* on NM_178837.4) | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV61275563; called by muse, mutect2, varscan2
- DNAH11 | c.13273G>T p.G4425C | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60944571; called by muse, varscan2
- DNAH3 | c.6288C>G p.Y2096* | Nonsense Mutation (SNP) | VAF 138/713 reads (19%) | catalogued as rs754658020, COSV54508908; called by muse, mutect2, varscan2
- DNAH9 | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as rs764052121, COSV52339207; called by muse, mutect2, varscan2
- DNAH9 | c.7694G>A p.R2565Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs147989905; called by muse, mutect2, varscan2
- DNAJC27 | c.682del p.A228Pfs*23 | Frame Shift Del (DEL) | VAF 46/237 reads (19%) | catalogued as rs760208198; called by mutect2, pindel, varscan2
- DOCK1 | c.4100G>A p.R1367Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs750915688, COSV54732875, COSV99733128; called by muse, mutect2, varscan2
- DOCK2 | c.1739C>G p.A580G | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV56946822; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 53/296 reads (18%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOP1B | c.2294T>C p.V765A | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs769078821, COSV101215487; called by muse, mutect2, varscan2
- DPP6 | c.905T>A p.I302N (on ENST00000377770 / NM_001364500.2; = p.I240N on NM_001936.5) | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59602524; called by muse, mutect2, varscan2
- DPP7 | c.1212_1213del p.R405Sfs*55 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | catalogued as COSV65371042; called by mutect2, pindel, varscan2
- DPYD | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60075893; called by muse, mutect2, varscan2
- DPYSL3 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1369407412, COSV100574965; called by muse, mutect2, varscan2
- DSCAML1 | c.2687G>A p.R896Q (on ENST00000321322; = p.R836Q on NM_020693.4) | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140050782, COSV100356729; called by muse, mutect2, varscan2
- DSP | c.6367C>T p.R2123C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372242085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYRK2 | c.1133G>A p.R378H (on ENST00000344096 / NM_006482.3; = p.R305H on NM_003583.4) | Missense Mutation (SNP) | VAF 122/310 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs543503984, COSV59845139, COSV59845482; called by muse, mutect2, varscan2
- DYRK4 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV50538105; called by muse, mutect2, varscan2
- E4F1 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs375039813; called by muse, mutect2, varscan2
- EBF1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 109/531 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.313); catalogued as rs775664953, COSV100565913; called by muse, mutect2, varscan2
- EBF2 | c.1532T>C p.M511T | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.071); catalogued as COSV68776597; called by muse, mutect2, varscan2
- ECPAS | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs773916820, COSV52193204, COSV52205786; called by muse, mutect2, varscan2
- EDA2R | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); catalogued as COSV53630579; called by muse, mutect2, varscan2
- EFCAB12 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs79535854, COSV58175108; called by muse, mutect2, varscan2
- EFHB | c.1415A>G p.Q472R | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99859675; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 39/151 reads (26%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EHD3 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs138474287; called by muse, mutect2, varscan2
- EHMT2 | c.1471C>A p.H491N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64994889; called by muse, mutect2, varscan2
- EIF3A | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs199796475, COSV64960613; called by muse, mutect2, varscan2
- EIF3D | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs745920273, COSV53402955; called by muse, mutect2, varscan2
- ELAVL1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs936268706, COSV100688388; called by muse, varscan2
- ELN | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52707995; called by muse, mutect2, varscan2
- ELOVL1 | c.838T>C p.*280Rext*6 | Nonstop Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as COSV60521801; called by muse, mutect2, varscan2
- ELOVL3 | c.4G>A p.V2I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100892805; called by muse, mutect2, varscan2
- ENDOU | c.551+1G>A p.X184_splice (on ENST00000422538 / NM_001172439.2; = p.X143_splice on NM_006025.4) | Splice Site (SNP) | VAF 153/747 reads (20%) | catalogued as rs150299683; called by muse, mutect2, varscan2
- ENPP5 | c.1241T>C p.I414T | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57908271; called by muse, mutect2, varscan2
- EPB41L3 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535892749, COSV59468132; called by muse, mutect2, varscan2
- EPHA5 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV56635316; called by muse, mutect2, varscan2
- EPHA6 | c.2465C>T p.P822L (on ENST00000389672 / NM_001080448.3; = p.P214L on NM_173655.4) | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.232); catalogued as rs371381556, COSV67563178; called by muse, mutect2, varscan2
- EPHB4 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs765819602, COSV62268185, COSV62268261; called by muse, mutect2, varscan2
- EPPK1 | c.5750G>A p.S1917N | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.211); catalogued as rs868913138, COSV73260927; called by muse, mutect2, varscan2
- ERICH1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100032586; called by muse, mutect2, varscan2
- ERICH3 | c.1218dup p.P407Tfs*7 | Frame Shift Ins (INS) | VAF 119/686 reads (17%) | catalogued as rs1441349703; called by mutect2, pindel, varscan2
- ESAM | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as COSV54033909; called by muse, mutect2, varscan2
- ESF1 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99176391; called by muse, varscan2
- ESPL1 | c.4676G>A p.R1559Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs766352133, COSV57757979; called by muse, mutect2, varscan2
- ESR1 | c.792G>T p.M264I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV52784313; called by muse, mutect2, varscan2
- EVI5L | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV99563233; called by muse, mutect2, varscan2
- EXO1 | c.1522del p.C508Afs*13 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs763386152; called by mutect2, pindel, varscan2
- EXPH5 | c.2348T>C p.I783T | Missense Mutation (SNP) | VAF 79/407 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99761725; called by muse, mutect2, varscan2
- EYS | c.615_616insG p.F206Vfs*10 | Frame Shift Ins (INS) | VAF 57/297 reads (19%) | catalogued as COSV60979079; called by mutect2, pindel, varscan2
- F10 | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs888321837, COSV65020989; called by muse, mutect2, varscan2
- F13A1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs761188694, COSV53555015; called by muse, mutect2, varscan2
- FAM114A2 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.492); catalogued as rs775272637, COSV61076820; called by muse, mutect2, varscan2
- FAM214B | c.1002dup p.S335Qfs*19 | Frame Shift Ins (INS) | VAF 17/74 reads (23%) | catalogued as rs775865641; called by mutect2, varscan2
- FANCA | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV101224879; called by muse, mutect2, varscan2
- FANCC | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV56657980; called by muse, mutect2, varscan2
- FARP2 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778378417, COSV99884792; called by muse, mutect2, varscan2
- FASTKD3 | c.428dup p.D144Gfs*3 | Frame Shift Ins (INS) | VAF 68/308 reads (22%) | catalogued as rs773607911; called by mutect2, varscan2
- FBXL7 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766340086, COSV61655466; called by muse, mutect2, varscan2
- FBXW2 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs368778140; called by muse, mutect2, varscan2
- FBXW7 | c.697G>T p.G233C (on ENST00000281708 / NM_001349798.2; = p.G153C on NM_018315.5) | Missense Mutation (SNP) | VAF 107/499 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV55962887, COSV99657673; called by muse, mutect2, varscan2
- FCMR | c.488-1G>A p.X163_splice | Splice Site (SNP) | VAF 57/304 reads (19%) | catalogued as rs763326970, COSV65567246; called by muse, mutect2, varscan2
- FCSK | c.683_685del p.F228del | In Frame Del (DEL) | VAF 44/224 reads (20%) | catalogued as rs752810500; called by pindel, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 41/199 reads (21%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FGD3 | c.367del p.Q123Rfs*51 | Frame Shift Del (DEL) | VAF 27/145 reads (19%) | catalogued as rs777351004, COSV100490512; called by mutect2, pindel, varscan2
- FGF17 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); catalogued as COSV63925405; called by muse, mutect2, varscan2
- FGGY | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1438571377, COSV58027937; called by muse, mutect2, varscan2
- FHIT | c.103+1G>A p.X35_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | catalogued as rs768812859, COSV104421355, COSV59290351; called by muse, mutect2, varscan2
- FHOD1 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 136/630 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs773788569, COSV50763643; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 42/186 reads (23%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIBCD1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV53392736; called by muse, mutect2, varscan2
- FILIP1L | c.3229C>A p.P1077T (on ENST00000354552 / NM_182909.3; = p.P837T on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/642 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as COSV100496943; called by mutect2, varscan2
- FKBP3 | c.79A>G p.K27E | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV53531492; called by muse, mutect2, varscan2
- FLI1 | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475468866, COSV99857834, COSV99858000; called by muse, mutect2, varscan2
- FLNC | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.079); catalogued as COSV100368230; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | catalogued as rs769482947; called by mutect2, varscan2
- FOXK1 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.375); catalogued as rs1172870281, COSV61064853; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs760347049; called by mutect2, varscan2
- FRRS1L | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs534260927, COSV73746413; called by muse, mutect2, varscan2
- FXR2 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as rs1260884806, COSV100002101; called by muse, mutect2, varscan2
- FYCO1 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV56114321; called by muse, mutect2, varscan2
- GAA | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs199748889, COSV56407372; ClinVar: uncertain significance; called by muse, varscan2
- GABBR1 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV63541455; called by muse, mutect2, varscan2
- GABBR1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.335); catalogued as rs769341923, COSV63541465; called by muse, mutect2, varscan2
- GABRA4 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 85/436 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409500965, COSV51932316; called by muse, varscan2
- GABRA5 | c.1065del p.A356Pfs*15 | Frame Shift Del (DEL) | VAF 40/192 reads (21%) | catalogued as rs758283106; called by mutect2, pindel, varscan2
- GAD2 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as rs776361193, COSV52152217; called by muse, mutect2, varscan2
- GAK | c.3734G>T p.G1245V | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58503374; called by muse, mutect2, varscan2
- GAL | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs762637870, COSV55763609; called by muse, mutect2, varscan2
- GANAB | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs748138975, COSV60462660; called by muse, mutect2, varscan2
- GAPVD1 | c.2762G>A p.R921H (on ENST00000394104; = p.R948H on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs138389331; called by muse, mutect2, varscan2
- GBP5 | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV58591882; called by muse, mutect2, varscan2
- GCLC | c.1297-1G>T p.X433_splice (on ENST00000643939; = p.X431_splice on NM_001498.4) | Splice Site (SNP) | VAF 12/232 reads (5%) | catalogued as COSV99988690; called by muse, mutect2
- GCN1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.578); catalogued as COSV56104949; called by muse, mutect2, varscan2
- GGT5 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs568293130, COSV54069012; called by muse, mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs771881138; called by mutect2, varscan2
- GIPC1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.973); catalogued as rs199560632; called by muse, mutect2, varscan2
- GLUD2 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60151486; called by muse, mutect2, varscan2
- GNAQ | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54108908; called by muse, mutect2, varscan2
- GNAQ | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54108920; called by muse, mutect2, varscan2
- GPANK1 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs774998575, COSV100789022; called by muse, mutect2, varscan2
- GPHN | c.1877G>T p.G626V (on ENST00000315266 / NM_001377519.1; = p.G659V on NM_020806.5) | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59474922; called by muse, mutect2, varscan2
- GPR173 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs1556805984; called by muse, mutect2
- GPR20 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148158345; called by muse, mutect2, varscan2
- GPR35 | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as COSV60576645; called by muse, mutect2, varscan2
- GPRASP1 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV64354999; called by muse, mutect2, varscan2
- GPRASP2 | c.1200G>T p.E400D | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); catalogued as COSV59990510, COSV59991956; called by muse, mutect2, varscan2
- GRIK4 | c.2219T>G p.I740S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101483628; called by muse, mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 25/111 reads (23%) | catalogued as COSV58051797; called by mutect2, pindel, varscan2
- GRIN2A | c.2663C>T p.T888M | Missense Mutation (SNP) | VAF 94/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149698593, COSV58018962; called by muse, mutect2, varscan2
- GRIN2C | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369969581; called by muse, mutect2, varscan2
- GRK6 | c.966C>T p.H322= | Splice Region (SNP) | VAF 39/171 reads (23%) | catalogued as rs199964997, COSV62682276; called by muse, mutect2, varscan2
- GRM2 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56583567; called by muse, mutect2, varscan2
- GRXCR1 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1246576319, COSV67670610; called by muse, mutect2, varscan2
- GUF1 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 145/655 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55781766; called by muse, mutect2, varscan2
- H1-10 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.019); catalogued as rs774541988, COSV61549580; called by muse, mutect2, varscan2
- H2AC13 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 47/366 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.306); catalogued as COSV62440393, COSV62440670; called by muse, mutect2, varscan2
- H4C7 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV55099505; called by muse, mutect2, varscan2
- HAPLN4 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138680442, COSV52269695; called by muse, mutect2, varscan2
- HCAR2 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61024470; called by muse, mutect2, varscan2
- HCK | c.9dup p.R4_?3 | Frame Shift Ins (INS) | VAF 32/200 reads (16%) | catalogued as rs755024531; called by mutect2, varscan2
- HCN1 | c.1128G>A p.M376I | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs191789690; called by muse, mutect2, varscan2
- HCN4 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99983845; called by muse, mutect2
- HEATR5A | c.4046G>T p.S1349I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66339073; called by muse, mutect2, varscan2
- HEG1 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs756958817, COSV100230106; called by muse, mutect2, varscan2
- HELB | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV99921964; called by muse, mutect2, varscan2
- HEPACAM2 | c.787G>A p.G263R (on ENST00000394468 / NM_001039372.4; = p.G251R on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59058396; called by muse, mutect2, varscan2
- HERC2 | c.8308T>C p.C2770R | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55312227; called by muse, mutect2, varscan2
- HHIPL2 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as COSV58563664; called by muse, mutect2, varscan2
- HLA-C | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100880612; called by muse, mutect2
- HMCES | c.827del p.K276Rfs*59 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs1259586777; called by mutect2, pindel, varscan2
- HMCN1 | c.8926G>A p.V2976I | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs772967670, COSV54884035; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | catalogued as rs767148651; called by mutect2, varscan2
- HOMEZ | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100664121, COSV62537411; called by muse, mutect2, varscan2
- HOXC10 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs757985930, COSV57725930; called by muse, mutect2, varscan2
- HOXC10 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV57725764; called by muse, mutect2, varscan2
- HOXD12 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV66832885; called by mutect2, varscan2
- HOXD4 | c.650A>G p.N217S | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100106887; called by muse, mutect2, varscan2
- HS6ST1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 68/444 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773632691, COSV52127130; called by muse, mutect2, varscan2
- HSPA1L | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989405; called by muse, mutect2, varscan2
- HTR3A | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs528104456, COSV55468629; called by muse, mutect2, varscan2
- ICE1 | c.5068C>T p.R1690C | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs369294963; called by muse, mutect2, varscan2
- ICMT | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1222141300, COSV59473116; called by muse, mutect2, varscan2
- IFI16 | c.12del p.K4Nfs*8 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | catalogued as rs1272199515; called by mutect2, pindel, varscan2
- IFNA17 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 88/358 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV69738108; called by muse, mutect2, varscan2
- IFT122 | c.1958C>T p.A653V (on ENST00000348417 / NM_052989.3; = p.A594V on NM_018262.4) | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs765879580, COSV99959423; called by muse, mutect2, varscan2
- IFT122 | c.3047G>A p.R1016Q (on ENST00000348417 / NM_052989.3; = p.R957Q on NM_018262.4) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs758998922, COSV99959427; called by muse, mutect2, varscan2
- IFT22 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100190074; called by muse, varscan2
- IFT22 | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1472526859, COSV59526920; called by muse, varscan2
- IGFBP6 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56857154; called by muse, mutect2, varscan2
- IGSF9B | c.3646C>A p.P1216T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); catalogued as COSV58064802; called by muse, mutect2, varscan2
- ILVBL | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375796907, COSV54619817; called by muse, mutect2, varscan2
- ILVBL | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54618376; called by muse, mutect2
- INSRR | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs377121387, COSV63871456; called by muse, mutect2, varscan2
- INSYN1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769380986, COSV101138824, COSV65837227; called by muse, mutect2, varscan2
- IPMK | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57266449; called by muse, mutect2, varscan2
- IPO4 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as COSV55778567; called by muse, mutect2, varscan2
- IPO8 | c.2531T>C p.L844P | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56240148; called by muse, varscan2
- IQGAP1 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs753859958, COSV51582469; called by muse, varscan2
- ISM2 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1298290021, COSV99376694; called by muse, mutect2, varscan2
- ITGAX | c.1841G>T p.R614M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99191767; called by muse, varscan2
- ITGB1BP2 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52136133; called by muse, mutect2, varscan2
- ITM2C | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200266468, COSV58398711; called by muse, mutect2, varscan2
- ITPRID1 | c.1401C>A p.D467E | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV60071528; called by muse, mutect2, varscan2
- ITPRID1 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV60071543; called by muse, mutect2, varscan2
- JAK1 | c.3094_3096del p.K1032del | In Frame Del (DEL) | VAF 47/251 reads (19%) | catalogued as COSV53805454; called by mutect2, pindel, varscan2
- JAK3 | c.115del p.Q39Sfs*108 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | catalogued as rs755706305; called by mutect2, pindel, varscan2
- JRK | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782654867, COSV101401108; called by muse, mutect2, varscan2
- KALRN | c.3343G>A p.V1115M | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954989552, COSV53755829; called by muse, mutect2, varscan2
- KANK1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs986771749, COSV63209808; called by muse, mutect2, varscan2
- KCNIP3 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 100/429 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as COSV54666598; called by muse, mutect2, varscan2
- KCNK5 | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV100851826; called by muse, mutect2
- KCNQ2 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60432318, COSV60435017; called by muse, mutect2, varscan2
- KCNS1 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as COSV60259522; called by muse, mutect2, varscan2
- KCTD15 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199530630; called by muse, mutect2, varscan2
- KCTD19 | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100430999; called by muse, mutect2, varscan2
- KDELR1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.08); catalogued as rs780757543, COSV58101721; called by muse, mutect2, varscan2
- KDM6B | c.4669G>A p.A1557T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as rs1257156719, COSV54678790; called by muse, mutect2, varscan2
- KHDC3L | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1184819856, COSV64868960; called by muse, mutect2, varscan2
- KHDRBS2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as rs372434154; called by muse, mutect2, varscan2
- KIAA0513 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as rs760211220, COSV99260943, COSV99261281; called by mutect2, varscan2
- KIDINS220 | c.3242del p.P1081Rfs*48 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | catalogued as COSV56750269; called by mutect2, pindel, varscan2
- KIF1B | c.4810G>A p.V1604I (on ENST00000377086 / NM_001365952.1; = p.V1558I on NM_015074.3) | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs769092155, COSV55804820; called by muse, mutect2, varscan2
- KIF26B | c.3199del p.R1067Gfs*65 | Frame Shift Del (DEL) | VAF 36/149 reads (24%) | catalogued as COSV63639593; called by mutect2, pindel, varscan2
- KIF27 | c.1766T>C p.L589S | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV52825938; called by muse, mutect2, varscan2
- KIF3C | c.996dup p.N333Efs*19 | Frame Shift Ins (INS) | VAF 30/172 reads (17%) | catalogued as rs748697767; called by mutect2, varscan2
- KIFC3 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1000625098, COSV65549277; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLHL4 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100909700; called by muse, mutect2
- KLHL8 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56747131; called by muse, mutect2, varscan2
- KLKB1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs777755728, COSV52994357; called by muse, mutect2, varscan2
- KMT2B | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.042); catalogued as rs750794495, COSV52889776; called by muse, mutect2, varscan2
- KNCN | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); catalogued as COSV53814413; called by muse, mutect2, varscan2
- KNOP1 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV54927001; called by muse, mutect2, varscan2
- KRBA2 | c.1135A>G p.N379D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV100497676; called by muse, mutect2, varscan2
- KRT19 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64238032; called by muse, mutect2, varscan2
- KRT4 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs769322571, COSV53406168; called by muse, mutect2, varscan2
- KRT81 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs767515484, COSV59809297; called by muse, mutect2, varscan2
- KRTAP10-2 | c.322del p.V108Cfs*238 | Frame Shift Del (DEL) | VAF 92/441 reads (21%) | catalogued as COSV59954680, COSV59954684; called by mutect2, varscan2
- KSR1 | c.593C>T p.T198M (on ENST00000644974 / NM_001367810.1; = p.T61M on NM_014238.2) | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs751430732, COSV52029234; called by muse, mutect2, varscan2
- L3MBTL4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV53115619; called by muse, mutect2, varscan2
- LAMA1 | c.6518G>A p.R2173Q | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs554700376, COSV67533383; called by muse, mutect2, varscan2
- LAMA2 | c.8759C>T p.A2920V | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs757583844, COSV70341484; called by muse, mutect2, varscan2
- LANCL2 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99634873; called by muse, mutect2, varscan2
- LARP1 | c.434del p.P145Qfs*10 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as COSV60428595; called by mutect2, varscan2
- LARP4B | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 37/233 reads (16%) | catalogued as COSV60220411; called by muse, mutect2, varscan2
- LCTL | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 41/157 reads (26%) | catalogued as rs539441696, COSV58421681, COSV58423324; called by muse, mutect2, varscan2
- LENG8 | c.1391del p.G464Afs*44 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as COSV58729808; called by mutect2, pindel, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LHX6 | c.397C>T p.R133W (on ENST00000373755 / NM_001242334.2; = p.R162W on NM_014368.5) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs756354677, COSV61344049; called by muse, mutect2, varscan2
- LIN54 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 87/471 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1382009808, COSV61200440; called by muse, mutect2, varscan2
- LIPE | c.1754T>C p.L585P | Missense Mutation (SNP) | VAF 84/440 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99734170; called by muse, varscan2
- LOXL1 | c.592T>C p.Y198H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56093727; called by muse, varscan2
- LPIN3 | c.1098del p.G368Afs*52 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs1185012518; called by mutect2, pindel, varscan2
- LRP1 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV54504543; called by muse, mutect2, varscan2
- LRP2BP | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs778371816, COSV53012264; called by muse, mutect2, varscan2
- LRRC49 | c.733T>C p.C245R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53008735; called by muse, mutect2, varscan2
- LRRCC1 | c.3091G>A p.D1031N | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV64482856; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470dup p.R491Tfs*14 | Frame Shift Ins (INS) | VAF 42/106 reads (40%) | catalogued as rs779699744; called by mutect2, varscan2
- LRRTM1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.817); catalogued as COSV54438776; called by muse, mutect2, varscan2
- MAD1L1 | c.951G>A p.W317* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as COSV56228870; called by muse, mutect2, varscan2
- MAN1B1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766402187, COSV65371040; called by muse, mutect2, varscan2
- MAP2K7 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs913866951, COSV101209062; called by muse, varscan2
- MAPK4 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68541333; called by muse, mutect2, varscan2
- MAPK8 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs200350498, COSV100827389, COSV64408556; called by muse, mutect2, varscan2
- MATN4 | c.1220G>A p.R407H (on ENST00000372754; = p.R366H on NM_003833.4) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | PolyPhen benign (0.063); catalogued as rs1193170482, COSV61350639; called by muse, mutect2, varscan2
- MC3R | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552943206, COSV54763275; called by muse, mutect2, varscan2
- MCM8 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54511623; called by muse, mutect2, varscan2
- MDFIC | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV57562574; called by muse, mutect2, varscan2
- MEP1B | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 64/295 reads (22%) | catalogued as rs200539508; called by muse, varscan2
- MGRN1 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 49/205 reads (24%) | catalogued as rs199984936, COSV52149117; called by muse, mutect2, varscan2
- MINDY1 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV100385451; called by muse, mutect2, varscan2
- MIOX | c.735G>T p.W245C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV53312103; called by muse, mutect2, varscan2
- MLNR | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs769275756, COSV99519927; called by muse, mutect2, varscan2
- MMP13 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV52823254; called by muse, mutect2, varscan2
- MMS19 | c.1642C>A p.Q548K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100512901; called by mutect2, varscan2
- MMS22L | c.2799del p.V934Ffs*8 | Frame Shift Del (DEL) | VAF 35/195 reads (18%) | catalogued as rs1562416103; called by mutect2, pindel, varscan2
- MN1 | c.3121G>A p.V1041M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.05); catalogued as COSV56556777, COSV56556789; called by muse, mutect2, varscan2
- MOK | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51963653; called by muse, mutect2, varscan2
- MORC4 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55239954, COSV55240159; called by muse, mutect2, varscan2
- MOV10 | c.2621G>A p.S874N | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV99588334; called by muse, mutect2
- MOXD1 | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs750766213, COSV60942307; called by muse, mutect2, varscan2
- MRE11 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs753717905, COSV60574608, COSV60577659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH1 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100395861; called by muse, mutect2, varscan2
- MRPS30 | c.1182G>T p.W394C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50181555; called by muse, mutect2, varscan2
- MSR1 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774834555, COSV50507879; called by muse, mutect2, varscan2
- MTA2 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV99545363; called by muse, mutect2, varscan2
- MTERF3 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs1175044683, COSV99749828; called by muse, varscan2
- MTMR11 | c.1437del p.W480Gfs*10 (on ENST00000439741 / NM_001145862.2; = p.W408Gfs*10 on NM_181873.3) | Frame Shift Del (DEL) | VAF 42/197 reads (21%) | catalogued as rs1559804082; called by mutect2, pindel, varscan2
- MTMR4 | c.60dup p.K21Qfs*20 | Frame Shift Ins (INS) | VAF 19/125 reads (15%) | catalogued as rs750261859; called by mutect2, varscan2
- MTOR | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100816280; called by muse, mutect2
- MTRES1 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1335440945, COSV60967731; called by muse, mutect2, varscan2
- MTUS2 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 51/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764265852, COSV70913437; called by muse, mutect2, varscan2
- MUC17 | c.5683A>G p.S1895G | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100073722; called by muse, mutect2, varscan2
- MUC4 | c.648C>G p.H216Q | Missense Mutation (SNP) | VAF 116/656 reads (18%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.234); catalogued as COSV62136165; called by muse, mutect2, varscan2
- MUC5B | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222570719, COSV101500418; called by muse, mutect2, varscan2
- MVD | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55367916; called by muse, mutect2, varscan2
- MXRA5 | c.6460C>T p.R2154W | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54226273; called by muse, mutect2, varscan2
- MYBBP1A | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs200728167, COSV54594832, COSV99626886; called by muse, mutect2, varscan2
- MYCBP2 | c.2954T>C p.L985P (on ENST00000357337; = p.L1023P on NM_015057.5) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62012367; called by muse, mutect2, varscan2
- MYH9 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs375738970; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO18B | c.5642A>G p.Q1881R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.8); catalogued as COSV59128188; called by muse, mutect2, varscan2
- MYO1F | c.289A>G p.M97V | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57792635; called by muse, varscan2
- MYO1F | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs570873153, COSV57792647; called by muse, varscan2
- MYO3A | c.4516G>A p.E1506K | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs779605870, COSV56322771; called by muse, mutect2, varscan2
- MYO9B | c.5179G>A p.G1727S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763492622, COSV68277654; called by muse, mutect2, varscan2
- MYOM1 | c.3376C>A p.P1126T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); catalogued as COSV55286971; called by muse, mutect2, varscan2
- MYT1L | c.2765G>A p.R922Q | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV67712308; called by muse, mutect2, varscan2
- N4BP1 | c.1829del p.N610Mfs*8 | Frame Shift Del (DEL) | VAF 84/454 reads (19%) | catalogued as rs1567431035; called by mutect2, pindel, varscan2
- NAA15 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.41); catalogued as COSV56718057; called by muse, varscan2
- NAGPA | c.1276+2T>C p.X426_splice | Splice Site (SNP) | VAF 24/159 reads (15%) | catalogued as COSV56569471; called by muse, mutect2, varscan2
- NARS1 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 80/420 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56876099; called by muse, mutect2, varscan2
- NBEAL1 | c.5998G>T p.A2000S | Missense Mutation (SNP) | VAF 109/498 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV101355535, COSV68917282; called by muse, mutect2, varscan2
- NCAPD3 | c.4202C>T p.S1401L | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs577629359, COSV73187766; called by muse, mutect2, varscan2
- NCKAP5L | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as COSV100258884; called by muse, mutect2, varscan2
- NECTIN1 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs768666517, COSV99872238; called by muse, mutect2, varscan2
- NEK10 | c.3167T>A p.L1056* | Nonsense Mutation (SNP) | VAF 61/244 reads (25%) | catalogued as COSV55356244; called by muse, mutect2, varscan2
- NELL1 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV54245713; called by muse, mutect2, varscan2
- NEURL4 | c.4490G>A p.R1497Q | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs752623474, COSV59747822; called by muse, mutect2, varscan2
- NF1 | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.19); catalogued as rs1306237220, COSV62195965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFASC | c.3154del p.T1052Lfs*13 | Frame Shift Del (DEL) | VAF 29/156 reads (19%) | catalogued as rs754233948; called by mutect2, pindel, varscan2
- NFATC1 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as rs752605795, COSV53696583; called by muse, mutect2, varscan2
- NFIL3 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 67/348 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99906935; called by muse, mutect2, varscan2
- NHEJ1 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs770861190, COSV59427621; called by muse, mutect2, varscan2
- NHS | c.4178A>G p.D1393G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as COSV66272448; called by muse, mutect2, varscan2
- NID1 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV51616232; called by muse, mutect2, varscan2
- NID2 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs774075467, COSV53493966; called by muse, mutect2, varscan2
- NINL | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs918417293, COSV54007611; called by muse, mutect2, varscan2
- NISCH | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs140213598; called by muse, mutect2, varscan2
- NKX2-5 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1363174603, COSV61298545; called by muse, mutect2, varscan2
- NKX6-1 | c.237del p.L80Sfs*23 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs745904099; called by mutect2, pindel, varscan2
- NLRP14 | c.1551C>A p.S517R | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV100205080; called by muse, mutect2, varscan2
- NOD2 | c.1515dup p.S506Vfs*73 | Frame Shift Ins (INS) | VAF 32/139 reads (23%) | catalogued as rs754761524; ClinVar: uncertain significance; called by mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as rs751187638; called by mutect2, varscan2
- NPAS4 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1412743010, COSV60649265; called by muse, mutect2, varscan2
- NPHS1 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62286803; called by muse, varscan2
- NPR3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV54085290; called by muse, mutect2, varscan2
- NR4A2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1465806325, COSV59893244; called by muse, varscan2
- NRP2 | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1415555640, COSV55922987, COSV55924608; called by muse, mutect2, varscan2
- NRXN2 | c.3023G>A p.R1008K | Missense Mutation (SNP) | VAF 124/488 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55449199; called by muse, mutect2, varscan2
- NRXN2 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1324774865, COSV55449208; called by muse, mutect2, varscan2
- NSD2 | c.2523del p.X841_splice | Splice Site (DEL) | VAF 12/62 reads (19%) | catalogued as COSV100373568; called by mutect2, pindel, varscan2
- NSD2 | c.3379A>G p.I1127V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.984); catalogued as COSV56387710; called by muse, mutect2, varscan2
- NSDHL | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100938661; called by muse, mutect2, varscan2
- NSG1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs766912597, COSV67574892; called by muse, mutect2, varscan2
- NSMAF | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs200846554, COSV50684576, COSV50695335; called by muse, mutect2, varscan2
- NT5C1B | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 66/328 reads (20%) | catalogued as rs1558394223; called by mutect2, varscan2
- NTF3 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV58417158, COSV58417973; called by muse, mutect2, varscan2
- NTNG2 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as rs1248440400, COSV62365181; called by muse, mutect2, varscan2
- NXN | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201764402, COSV100403162; called by muse, mutect2, varscan2
- NYNRIN | c.5447G>A p.R1816H | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs775804688, COSV66844047; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 56/230 reads (24%) | catalogued as rs762005098; called by mutect2, varscan2
- OGFR | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.673); catalogued as COSV51697223; called by muse, mutect2, varscan2
- OLIG3 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV62988316; called by muse, mutect2, varscan2
- OPALIN | c.426A>C p.*142Cext*47 | Nonstop Mutation (SNP) | VAF 42/170 reads (25%) | catalogued as COSV64520410; called by muse, varscan2
- OPLAH | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101470780; called by muse, mutect2, varscan2
- OR10G7 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 88/377 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100389968, COSV57866023; called by muse, mutect2, varscan2
- OR13C2 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV101604877; called by muse, mutect2, varscan2
- OR13C4 | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52926081; called by muse, mutect2, varscan2
- OR1B1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs759389860, COSV59171355; called by muse, mutect2, varscan2
- OR1J2 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100093272, COSV58944739; called by muse, mutect2, varscan2
- OR1L8 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs139416140, COSV59185978; called by muse, mutect2, varscan2
- OR1N1 | c.306T>G p.F102L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.708); catalogued as COSV59195175; called by muse, mutect2, varscan2
- OR51V1 | c.486del p.I163Sfs*4 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs573294390; called by mutect2, pindel, varscan2
- OR52N5 | c.946T>C p.F316L | Missense Mutation (SNP) | VAF 64/441 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100399709; called by muse, mutect2, varscan2
- OR5D14 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV59455687; called by muse, mutect2, varscan2
- OR5L1 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100450076; called by muse, mutect2, varscan2
- OR5M8 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59115970; called by muse, mutect2, varscan2
- OR8S1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs777773697, COSV100043593, COSV59600504; called by muse, mutect2, varscan2
- OR9A2 | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV63306378; called by muse, mutect2, varscan2
- OR9K2 | c.846del p.F282Lfs*12 (on ENST00000305377; = p.F260Lfs*12 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 50/262 reads (19%) | catalogued as rs766045796, COSV59532170; called by mutect2, varscan2
- ORMDL3 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs774130627, COSV58345655; called by muse, mutect2, varscan2
- OSBP2 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs759958825, COSV60240569; called by muse, varscan2
- OSBPL7 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV50107187; called by muse, mutect2, varscan2
- OTOGL | c.6501del p.K2167Nfs*40 (on ENST00000547103; = p.K2158Nfs*40 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/128 reads (15%) | catalogued as rs1361238129, COSV54012775; called by mutect2, pindel, varscan2
- OTUD4 | c.1405G>A p.A469T (on ENST00000447906 / NM_001366057.1; = p.A404T on NM_001102653.1) | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV71381601; called by muse, mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- PACS2 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs1555412324, COSV57653844; called by muse, mutect2, varscan2
- PAK4 | c.196del p.A66Pfs*29 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as COSV100426419; called by mutect2, pindel, varscan2
- PAQR9 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs754864265, COSV61417720; called by muse, mutect2, varscan2
- PARD6G | c.940del p.Q314Rfs*78 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs755217812; called by mutect2, pindel, varscan2
- PAX1 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68271294; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 25/154 reads (16%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBX1 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.225); catalogued as COSV63341783; called by muse, mutect2, varscan2
- PCDH15 | c.5679A>C p.E1893D | Missense Mutation (SNP) | VAF 85/433 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV57273015; called by muse, mutect2, varscan2
- PCDHA4 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63543952, COSV63546049; called by muse, mutect2, varscan2
- PCDHA6 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.057); catalogued as rs1554132505, COSV65342535; called by muse, mutect2, varscan2
- PCDHA7 | c.2149C>A p.L717M | Missense Mutation (SNP) | VAF 99/501 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV65335262; called by muse, mutect2, varscan2
- PCDHA8 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV65324151; called by muse, mutect2, varscan2
- PCDHA9 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 137/651 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV65324163; called by muse, varscan2
- PCDHB9 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs782496466; called by muse, mutect2, varscan2
- PCDHGB2 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.086); catalogued as COSV53912651; called by muse, mutect2, varscan2
- PCDHGC5 | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99340565; called by muse, mutect2, varscan2
- PCSK7 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs757871447, COSV58006203; called by muse, mutect2, varscan2
- PDE1A | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 68/367 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV59517219; called by muse, mutect2, varscan2
- PDE3A | c.284C>A p.A95E | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV62969565; called by muse, mutect2, varscan2
- PDE6C | c.221del p.G74Afs*69 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs770812539, COSV101008853; called by mutect2, pindel, varscan2
- PDLIM2 | c.401G>T p.S134I (on ENST00000397760; = p.S384I on NM_021630.6) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV56131965; called by muse, mutect2, varscan2
- PDLIM5 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV58746019; called by muse, mutect2, varscan2
- PER1 | c.23C>A p.A8D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV100424612; called by muse, mutect2
- PES1 | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV58828040; called by muse, mutect2, varscan2
- PHETA2 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs146670018; called by muse, mutect2, varscan2
- PHF12 | c.2645del p.P882Qfs*30 | Frame Shift Del (DEL) | VAF 53/270 reads (20%) | catalogued as rs767725558; called by mutect2, pindel, varscan2
- PHF2 | c.185T>C p.L62S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV63679277; called by muse, mutect2, varscan2
- PHF6 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as rs1302895379, COSV100136577; called by muse, mutect2, varscan2
- PID1 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 58/262 reads (22%) | catalogued as COSV101237091; called by muse, mutect2, varscan2
- PIM2 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV55944093; called by muse, mutect2, varscan2
- PITPNM1 | c.1328C>A p.P443H | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.525); catalogued as COSV62707641; called by muse, mutect2, varscan2
- PJA2 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV63272070; called by muse, varscan2
- PKLR | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs148435198, COSV61360968, COSV61361375; called by muse, mutect2, varscan2
- PLA2G15 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1273609693, COSV54718087; called by muse, mutect2, varscan2
- PLA2G4D | c.1624C>A p.L542I | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.045); catalogued as COSV51819568; called by muse, mutect2, varscan2
- PLAT | c.912del p.Y304* | Frame Shift Del (DEL) | VAF 22/156 reads (14%) | catalogued as COSV54274564; called by mutect2, pindel, varscan2
- PLCE1 | c.4246C>A p.L1416I | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53341256; called by muse, mutect2, varscan2
- PLCL1 | c.998A>C p.N333T | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV101407042; called by muse, mutect2
- PLEC | c.6233A>C p.K2078T (on ENST00000322810 / NM_201380.4; = p.K1968T on NM_000445.5) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as CD127943, COSV100515184; called by muse, mutect2, varscan2
- PLEKHH2 | c.1167del p.K389Nfs*23 | Frame Shift Del (DEL) | VAF 24/129 reads (19%) | catalogued as COSV56749415; called by mutect2, pindel, varscan2
- PLIN5 | c.257-1G>A p.X86_splice | Splice Site (SNP) | VAF 11/59 reads (19%) | catalogued as COSV67850449; called by muse, mutect2, varscan2
- PLS1 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as COSV61833066; called by muse, mutect2, varscan2
- PLXNA4 | c.1928G>A p.G643D | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58110868; called by muse, mutect2, varscan2
- PLXNC1 | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs763485097, COSV51571053, COSV99313998; called by muse, mutect2, varscan2
- PLXND1 | c.4025G>A p.R1342H | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs769351907, COSV60710279; called by muse, mutect2, varscan2
- POGLUT2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs36094126; called by muse, mutect2, varscan2
- POLN | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.043); catalogued as COSV67023866; called by muse, mutect2, varscan2
- POLR3F | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 61/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101112298; called by muse, mutect2, varscan2
- POM121 | c.794G>T p.R265M | Missense Mutation (SNP) | VAF 85/441 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1563155794, COSV99988498; called by muse, mutect2, varscan2
- POM121 | c.2947G>A p.A983T (on ENST00000434423; = p.A718T on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs781840104, COSV57514337; called by muse, mutect2, varscan2
- POMT1 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 96/515 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57644548; called by muse, mutect2, varscan2
- PPFIBP1 | c.3007A>G p.S1003G (on ENST00000318304 / NM_177444.3; = p.S997G on NM_003622.4) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as COSV57288818; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 38/198 reads (19%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPP1R13L | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV62909550; called by muse, mutect2, varscan2
- PPP1R15B | c.2107T>C p.C703R | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs931122229, COSV65815440; called by muse, mutect2, varscan2
- PPP1R16A | c.1333del p.H445Tfs*15 | Frame Shift Del (DEL) | VAF 63/313 reads (20%) | catalogued as rs777096925; called by mutect2, pindel, varscan2
- PPP1R18 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.712); catalogued as rs1036923686, COSV51294820; called by muse, mutect2, varscan2
- PPP4R4 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV58552809; called by muse, mutect2, varscan2
- PRDM16 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748880850, COSV54582073; called by muse, mutect2, varscan2
- PRDM16 | c.1536del p.G513Afs*27 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | catalogued as COSV54605512; called by mutect2, pindel, varscan2
- PRDM2 | c.2248C>A p.L750I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV52443885; called by muse, mutect2, varscan2
- PRDM5 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 101/503 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV53357227; called by muse, mutect2, varscan2
- PRKCI | c.826dup p.T276Nfs*16 | Frame Shift Ins (INS) | VAF 50/306 reads (16%) | catalogued as rs753143066; called by mutect2, varscan2
- PRKCSH | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV52950590; called by muse, mutect2, varscan2
- PRMT6 | c.1080A>C p.K360N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100791204; called by mutect2, varscan2
- PROX1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.427); catalogued as rs1445422874, COSV54784966; called by muse, mutect2, varscan2
- PRPF8 | c.6179G>C p.S2060T | Missense Mutation (SNP) | VAF 108/434 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV56772866; called by muse, mutect2, varscan2
- PRPSAP2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV52064716; called by muse, mutect2, varscan2
- PRR14 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as rs749081660, COSV54910979; called by muse, mutect2, varscan2
- PRRC2B | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs1483140843, COSV100621364, COSV61934761; called by muse, mutect2, varscan2
- PRRT3 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765349938, COSV99926563; called by mutect2, varscan2
- PSG2 | c.986T>G p.L329R | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV100283561, COSV61545508; called by muse, mutect2, varscan2
- PTCH2 | c.2996T>C p.M999T | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs149189451, COSV64710218; called by muse, mutect2, varscan2
- PTK7 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57847141; called by muse, mutect2, varscan2
- PTPRH | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV99671095; called by muse, mutect2, varscan2
- PTPRK | c.3362G>A p.R1121H (on ENST00000368215 / NM_001291984.2; = p.R1122H on NM_002844.4) | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs758400881, COSV63892901; called by muse, mutect2, varscan2
- PUDP | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV66903417; called by muse, mutect2, varscan2
- PUF60 | c.1162C>T p.P388S (on ENST00000526683 / NM_001362896.2; = p.P371S on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV57583432; called by muse, mutect2, varscan2
- PURG | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV53297054, COSV99988875; called by muse, mutect2, varscan2
- R3HDM1 | c.1651A>G p.M551V | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs770463635, COSV51521862; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV54758727; called by muse, mutect2, varscan2
- RAB3C | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs1371489376, COSV51432573; called by muse, mutect2, varscan2
- RAB3GAP2 | c.947_949del p.F316del | In Frame Del (DEL) | VAF 29/146 reads (20%) | catalogued as rs1558151600; called by pindel, varscan2
- RAMP3 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs757054812, COSV54245235; called by mutect2, varscan2
- RANBP10 | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100449334; called by muse, mutect2, varscan2
- RAPGEF4 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as rs199578267; called by muse, mutect2, varscan2
- RAPGEF4 | c.2472G>T p.Q824H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51380855; called by muse, mutect2, varscan2
- RARA | c.1286del p.G429Vfs*214 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs1567767560; called by mutect2, pindel
- RASGRF1 | c.1954A>G p.S652G | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV101174551; called by muse, mutect2, varscan2
- RASGRF2 | c.2254A>G p.N752D | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.119); catalogued as COSV54124694; called by muse, mutect2, varscan2
- RBAK | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as rs200186724, COSV62330935; called by muse, mutect2, varscan2
- RBBP6 | c.4423dup p.T1475Nfs*2 | Frame Shift Ins (INS) | VAF 16/128 reads (13%) | catalogued as rs747289496; called by mutect2, varscan2
- RBM15 | c.1498C>A p.L500M | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63923202; called by muse, mutect2, varscan2
- RBMS3 | c.248+1G>A p.X83_splice | Splice Site (SNP) | VAF 37/170 reads (22%) | catalogued as rs755590204, COSV56135798; called by muse, mutect2, varscan2
- RBMS3 | c.792-1G>T p.X264_splice | Splice Site (SNP) | VAF 120/652 reads (18%) | catalogued as COSV99822061; called by mutect2, varscan2
- REG1A | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV52068998; called by muse, mutect2, varscan2
- RENBP | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60070105; called by muse, mutect2, varscan2
- REST | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58359725; called by muse, mutect2, varscan2
- REXO1 | c.3443T>C p.L1148P | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50075427; called by muse, mutect2, varscan2
- REXO5 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257851398, COSV99759252; called by muse, mutect2, varscan2
- RGS7BP | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as rs770968906, COSV61833602; called by muse, mutect2, varscan2
- RHPN1 | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56645298; called by muse, mutect2, varscan2
- RHPN2 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761330344, COSV54276090; called by muse, mutect2, varscan2
- RIC1 | c.2650C>T p.L884F | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399016392, COSV52606196; called by muse, mutect2, varscan2
- RIC1 | c.3497A>G p.N1166S | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776829636, COSV52606208; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RINL | c.1573C>T p.R525C (on ENST00000591812 / NM_001195833.2; = p.R411C on NM_198445.4) | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1568384821, COSV61574165; called by muse, mutect2, varscan2
- RIPK3 | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99353266; called by muse, mutect2, varscan2
- RLF | c.2249A>G p.Y750C | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV65650947; called by muse, mutect2, varscan2
- RNF123 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs150915433; called by muse, mutect2, varscan2
- RNF145 | c.1048G>A p.V350I (on ENST00000424310 / NM_001199383.2; = p.V378I on NM_144726.2) | Missense Mutation (SNP) | VAF 71/432 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as rs778925094, COSV50864802; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 58/134 reads (43%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RNH1 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs200324639, COSV62250491; called by muse, mutect2, varscan2
- RP1L1 | c.3797C>T p.A1266V | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV66752825; called by muse, mutect2, varscan2
- RPE65 | c.418G>T p.G140W | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52013915; called by muse, mutect2, varscan2
- RPL12 | c.123del p.V42Lfs*15 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as COSV55941066; called by mutect2, pindel
- RPL8 | c.500-1G>T p.X167_splice | Splice Site (SNP) | VAF 26/137 reads (19%) | catalogued as COSV52798993; called by muse, mutect2, varscan2
- RPS2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51909593; called by muse, mutect2, varscan2
- RTKN2 | c.1788A>C p.K596N | Missense Mutation (SNP) | VAF 91/418 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV59521659; called by muse, mutect2, varscan2
- RTL3 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV58183461; called by muse, mutect2, varscan2
- RTP1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99044213; called by muse, mutect2, varscan2
- RTP2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.984); catalogued as rs141211808; called by muse, mutect2, varscan2
- RTP5 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs768854977, COSV58319270; called by muse, mutect2, varscan2
- RUVBL1 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100494206; called by muse, mutect2, varscan2
- RXFP3 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as COSV57504472, COSV57506141; called by muse, mutect2, varscan2
- S1PR5 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV61013453; called by muse, mutect2, varscan2
- SAFB | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV52650113; called by muse, mutect2, varscan2
- SARS2 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99671378; called by muse, mutect2, varscan2
- SASS6 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs774060441, COSV54926900; called by muse, mutect2, varscan2
- SCAP | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs772986145, COSV99652860; called by muse, varscan2
- SCG2 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs368049148; called by muse, mutect2, varscan2
- SCN1A | c.4892C>A p.S1631Y (on ENST00000303395 / NM_001202435.3; = p.S1620Y on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100320758; called by muse, mutect2, varscan2
- SCN2A | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 77/363 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs387906686, CM106922, COSV51834971; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SCN5A | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs749651069, COSV61118544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRIB | c.503+1G>A p.X168_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as rs753969093, COSV57583425; called by muse, mutect2, varscan2
- SDF2L1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs775215919, COSV50707804; called by muse, mutect2, varscan2
- SECISBP2L | c.1413del p.K471Nfs*20 (on ENST00000559471 / NM_001193489.2; = p.K426Nfs*20 on NM_014701.4) | Frame Shift Del (DEL) | VAF 44/168 reads (26%) | catalogued as rs768725524; called by mutect2, varscan2
- SELENON | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100823515; called by muse, mutect2, varscan2
- SELENOO | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938903101, COSV66599786; called by muse, mutect2, varscan2
- SEMA3D | c.1897C>T p.H633Y | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.24); catalogued as COSV99406781, COSV99406925; called by muse, mutect2, varscan2
- SEMA4G | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV52966779, COSV52970912; called by muse, mutect2, varscan2
- SERPINA6 | c.1191C>G p.F397L | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.521); catalogued as COSV58583411, COSV58583818; called by muse, mutect2, varscan2
- SERPINA9 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs865864584, COSV54073318; called by muse, mutect2, varscan2
- SERPINH1 | c.1057C>A p.H353N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63997799; called by muse, mutect2, varscan2
- SF3B6 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV51980149; called by muse, mutect2, varscan2
- SFRP2 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV56837057, COSV56837898; called by muse, mutect2, varscan2
- SGPP1 | c.512T>C p.M171T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1326042787, COSV55974729; called by muse, mutect2, varscan2
- SH2D3C | c.1033G>A p.V345I (on ENST00000314830 / NM_170600.3; = p.V188I on NM_005489.4) | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs199532954, COSV100137504, COSV59119642; called by muse, mutect2, varscan2
- SH3BP2 | c.1140dup p.V381Rfs*14 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | catalogued as rs759199606; called by mutect2, pindel, varscan2
- SH3RF2 | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs753470880, COSV63037716; called by muse, mutect2, varscan2
- SHOX | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 125/561 reads (22%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs773266910, COSV61861878; called by muse, mutect2, varscan2
- SHPRH | c.1371del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 25/131 reads (19%) | catalogued as rs774210627; called by mutect2, pindel, varscan2
- SIDT2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs749620357, COSV54055844; called by muse, mutect2, varscan2
- SIGLEC5 | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV55778054; called by muse, mutect2
- SIN3B | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs1172751156, COSV56130873; called by muse, mutect2, varscan2
- SIRT3 | c.872T>G p.I291S | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66953218; called by muse, mutect2, varscan2
- SLAMF9 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 77/364 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV63636355; called by muse, mutect2, varscan2
- SLC16A6 | c.294del p.L99Yfs*39 | Frame Shift Del (DEL) | VAF 19/85 reads (22%) | catalogued as rs782184620; called by mutect2, pindel, varscan2
- SLC1A2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145275821; called by muse, mutect2, varscan2
- SLC22A13 | c.637+1G>A p.X213_splice | Splice Site (SNP) | VAF 40/156 reads (26%) | catalogued as rs373202002; called by muse, varscan2
- SLC24A3 | c.1849C>A p.L617M | Missense Mutation (SNP) | VAF 116/550 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV60113756; called by muse, mutect2, varscan2
- SLC26A8 | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 97/522 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV62884937; called by muse, mutect2, varscan2
- SLC35B4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV65984413; called by muse, mutect2, varscan2
- SLC39A8 | c.852del p.E285Sfs*8 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | catalogued as rs1560527212; called by mutect2, pindel, varscan2
- SLC40A1 | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 78/313 reads (25%) | catalogued as COSV53722240; called by muse, mutect2, varscan2
- SLC41A1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV65650175; called by muse, mutect2, varscan2
- SLC44A1 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66024881; called by muse, mutect2, varscan2
- SLC44A4 | c.431dup p.N144Kfs*55 | Frame Shift Ins (INS) | VAF 49/236 reads (21%) | catalogued as rs764603659; called by mutect2, pindel, varscan2
- SLC49A3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as rs762958700, COSV59139668; called by muse, mutect2, varscan2
- SLC7A2 | c.504del p.F168Lfs*9 (on ENST00000494857 / NM_001370338.1; = p.F208Lfs*9 on NM_003046.6) | Frame Shift Del (DEL) | VAF 56/330 reads (17%) | catalogued as rs780138939; called by mutect2, pindel, varscan2
- SLC9C1 | c.2014del p.S672Hfs*9 | Frame Shift Del (DEL) | VAF 24/151 reads (16%) | catalogued as rs761139813; called by mutect2, pindel, varscan2
- SLF2 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as rs1212696529, COSV53279278; called by muse, mutect2, varscan2
- SLFNL1 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV57234218; called by muse, mutect2, varscan2
- SLX4 | c.4918G>T p.G1640W | Missense Mutation (SNP) | VAF 70/328 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV99568129; called by muse, mutect2, varscan2
- SMARCC1 | c.3131C>T p.S1044F | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as COSV54378197; called by muse, mutect2, varscan2
- SMCHD1 | c.3893T>C p.V1298A | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV55252909; called by muse, mutect2, varscan2
- SMYD3 | c.1102G>A p.V368I (on ENST00000490107 / NM_001375962.1; = p.V309I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs138010213; called by muse, mutect2, varscan2
- SMYD4 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV59710832; called by muse, mutect2, varscan2
- SNAPC1 | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99359274; called by muse, mutect2, varscan2
- SNAPIN | c.333_334del p.H111Qfs*52 | Frame Shift Del (DEL) | VAF 42/220 reads (19%) | catalogued as rs766526649; called by pindel, varscan2
- SNRPA | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs775580802, COSV54681816; called by muse, mutect2, varscan2
- SNX13 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV101285181, COSV68064147; called by muse, mutect2, varscan2
- SNX31 | c.146G>T p.R49M | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV100310190; called by muse, mutect2, varscan2
- SNX5 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66623986; called by muse, mutect2, varscan2
- SOWAHA | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as rs763068818, COSV66332346; called by muse, mutect2, varscan2
- SOX17 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1403034582, COSV52024724; called by muse, mutect2, varscan2
- SPAG16 | c.1044del p.F348Lfs*8 | Frame Shift Del (DEL) | VAF 33/191 reads (17%) | catalogued as rs1198212557; called by mutect2, pindel, varscan2
- SPART | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV62084071; called by muse, mutect2, varscan2
- SPATA18 | c.1563+2T>C p.X521_splice | Splice Site (SNP) | VAF 30/120 reads (25%) | catalogued as COSV54642371; called by muse, varscan2
- SPATC1 | c.595del p.L199Sfs*20 | Frame Shift Del (DEL) | VAF 24/183 reads (13%) | catalogued as rs782440109; called by mutect2, pindel, varscan2
- SPEM2 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV60366309; called by muse, mutect2, varscan2
- SPEN | c.2530C>T p.R844* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV65358929; called by muse, mutect2, varscan2
- SPICE1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs148983792; called by muse, varscan2
- SPINK4 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65687869; called by muse, mutect2, varscan2
- SPON1 | c.1498T>A p.S500T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.107); catalogued as COSV100116044; called by muse, mutect2
- SPPL2A | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as COSV55940137; called by muse, mutect2, varscan2
- SPRR3 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV54878939; called by mutect2, varscan2
- SPX | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV57020317; called by muse, mutect2, varscan2
- SRCIN1 | c.1691C>T p.A564V (on ENST00000621492; = p.A530V on NM_025248.3) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs770791045; called by muse, mutect2, varscan2
667 further variants in this file (335 protein-altering or splice-affecting, 309 silent, 23 other) are not listed here.
